Gene-level copy-number profile of tumor specimen TCGA-HU-A4G6-01A from TCGA case TCGA-HU-A4G6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.5 years (27,208 days).
Specimen TCGA-HU-A4G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.20045453-b528-4717-8660-eb7e94091c99.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4G6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32d63d94-b328-4992-a9ef-ec7d64969d54

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 2,356; copy number 3: 38,297; copy number 4: 13,458; copy number 5: 5,515; copy number 6: 77; copy number 39: 115.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4G6-01A-11D-A24C-01): tumor purity 0.81, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 115 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:39,566,915–41,302,851, 115 genes, copy number 39 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
